Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6394, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6394-01A (Primary Tumor).

HOSP. NO.:
ORDERING PHYSICIAN

PATH. NO:

TCGA-DU-6394

NAME:
AGE/SEX:

SURGERY DATE:
RECEIVE DATE:

PHYSICIAN:

PATHOLOGICAL DIAGNOSIS:

RIGHT FRONTAL LOBE: OLIGODENDROGLIOMA, ANAPLASTIC, PROLIFERATIVE
INDEX (MIB -1) 15 - 20%.

Operation/Specimen: Right frontal lobe.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY: Specimen A, labeled "frontal lobe tumor", is a 3 x 2 x 1.5 cm. gray-brown tissue. A portion of the specimen has been examined by frozen section and is submitted in cassette 1, remaining tissue in cassettes 2&3. Frozen section diagnosis: Glioma.

Specimen B, labeled "right frontal lobectomy", is a portion of brain tissue 4.5 x 3 x 2 cm. multiple sections through the specimen show no grossly identifiable tumor tissue. Representative sections are submitted in cassettes 4-9.

MICROSCOPIC: There is a high cellular oligodendroglioma with scattered calcification. The tumor diffusely infiltrates the cortex where prominent neuronal satellitosis and subpial extensions are noted. The tumor shows moderate subepithelial nuclear pleomorphism and frequent mitoses. Endothelial hyperplasia is mild and tumor necrosis is not seen. Immunohistochemical stain for Ki67 with monoclonal antibody MIB-1 reveal that the tumor has a proliferative index of 15-20%.

Source: NCI Genomic Data Commons file 0961abee-6a7b-49eb-81ec-4d1e2f0ed675 (TCGA-DU-6394.300D6B45-FF77-493D-9B07-9921AE4569BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).